Somatic mutation profile of tumor specimen TCGA-S9-A6U9-01A (aliquot TCGA-S9-A6U9-01A-11D-A32B-08) from TCGA case TCGA-S9-A6U9, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 36.9 years (13,460 days).
Specimen TCGA-S9-A6U9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 105712dc-6e59-4a31-8d5d-46fb52a4780a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6U9-10A (Blood Derived Normal), aliquot TCGA-S9-A6U9-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ca1e63d-0df0-4377-b5ab-4d1b2bc3bcf0

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7, Frame Shift Del 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANXA10 | c.723T>C p.I241= | Splice Region (SNP) | VAF 6/8 reads (75%) | catalogued as COSV63738280; called by muse, mutect2, varscan2
- ATN1 | c.809C>G p.A270G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.023); catalogued as COSV100755986; called by muse, mutect2, varscan2
- CFAP61 | c.2866G>T p.V956L | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs771735943, COSV99846882; called by muse, mutect2, varscan2
- CSPP1 | c.2726A>G p.D909G (on ENST00000676605; = p.D868G on NM_024790.6) | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.51); catalogued as COSV99140123; called by muse, mutect2, varscan2
- IL13RA1 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV100861764; called by muse, mutect2, varscan2
- MAN1C1 | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56041932; called by muse, mutect2, varscan2
- NRXN3 | c.2778-2A>G p.X926_splice (on ENST00000335750 / NM_001330195.2; = p.X553_splice on NM_004796.6) | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100209988; called by muse, mutect2, varscan2
- PHF3 | c.2779A>G p.I927V | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV100014120; called by muse, mutect2, varscan2
- SF3B2 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV100488701; called by muse, mutect2
- SNX31 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV100310596; called by muse, mutect2, varscan2
- SNX9 | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as rs187768612; called by muse, mutect2, varscan2
- ATRX | c.4259_4260del p.K1420Tfs*9 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | called by pindel, varscan2
- MAP3K1 | c.2246_2274del p.N749Mfs*5 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel
- SIK2 | c.2148-19_2152del p.X716_splice | Splice Site (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel
- BTBD7 | c.1308G>A p.S436= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs1480510990, COSV100598280; called by muse, mutect2, varscan2
- ITIH1 | c.1933C>T p.L645= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV99835671; called by muse, mutect2, varscan2
- MARCHF10 | c.2016C>T p.P672= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100248695; called by muse, mutect2, varscan2
- OR5AP2 | c.459C>G p.T153= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100266480; called by muse, mutect2, varscan2
- PKHD1 | c.12069C>T p.D4023= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs781101323, COSV100945486; called by muse, mutect2, varscan2
- VGLL2 | c.477C>T p.G159= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2, varscan2
- VWA2 | c.711C>G p.V237= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs368890749, COSV100074028; called by muse, mutect2, varscan2
